Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7783, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7783-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] male with a history of PSA value of 12.8. The patient also has a history of biopsy revealing: Poorly differentiated prostatic adenocarcinoma Gleason score 3+4 = 7 in the right mid and moderately differentiated prostatic adenocarcinoma Gleason score 3+3 = 6 in the remaining right lobe (specimen unavailable). The patient's paternal uncle has a history of prostate cancer. The patient also has a history of umbilical hernia repair, hypertension, hypercholesterolemia.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION –

NO EVIDENCE OF NEOPLASIA IN FOUR LYMPH NODES (0/4).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION –

NO EVIDENCE OF NEOPLASIA IN THIRTEEN LYMPH NODES (0/13).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4+3=7.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST DIAMETER OF 1.6 CM IN ONE HISTOLOGIC SECTION.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 20% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION IN THE POSTERIOR RIGHT MID REGION (SLIDE 3T).
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. THE SURGICAL MARGINS OF FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (HG-PIN) IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- K. BACKGROUND PROSTATE TISSUE WITH BENIGN PROSTATIC HYPERPLASIA AND FOCAL ATROPHY.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 12.8
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	55%
WEIGHT OF PROSTATE:	54.33gm
TUMOR SIZE:	Maximum dimension: 1.6 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	17
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file e3e120d9-9a7e-4abb-9c33-1be4bfd35ca8 (TCGA-EJ-7783.8C4EAB7F-E0E2-4CAD-B06C-AE2D3ED11052.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).